TCGA case TCGA-BP-4760 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4cfe4f31-f62c-423a-8b9f-17f455b15313

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,268 days); Year of diagnosis: 2004; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -3,080 days (-8.4 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.2 years (26,725 days); Days to diagnosis: 1,457 days (4.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 1,457 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,249 days (6.2 years); Disease response: With Tumor.
- Days to follow up: 2,361 days (6.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Calcium: Low.
- Leukocytes: Elevated.
- Platelets: Normal.
- Hemoglobin: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-BP-4760-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 1.
  Slide TCGA-BP-4760-01A-01-BS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent necrosis: 0; Percent stromal cells: 2; Percent lymphocyte infiltration: 1.
- Sample TCGA-BP-4760-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4760-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Lymph nodes examined: No.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Locoregional.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: 66.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Prior malignancy prostate cancer treated with locoregional radiation. Patient with synchronous malignancy of R KIRC.
- Prior malignancy: Prior malignancy prostate cancer treated with locoregional radiation. Patient with synchronous malignancy of R KIRC.
- Synchronous malignancy: Prior malignancy prostate cancer treated with locoregional radiation. Patient with synchronous malignancy of R KIRC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,361 days; disease-specific survival: no event (censored), 2,361 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,457 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BP-4760-01A-02D-1417-01): tumor purity 0.55, ploidy 2, whole-genome doublings 0.
